Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A1GC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A1GC-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REVISED REPORT

1CD-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium c54.1

Case Number :

1/31/11

h

Diagnosis:

A: Lymph nodes, left peri-aortic, lymph node dissection

- Two lymph nodes, no tumor seen (0/2).

B: Lymph nodes, right peri-aortic, lymph node dissection

- Ten lymph nodes, no tumor seen (0/10).

C: Lymph nodes, left pelvic, lymph node dissection

- Six lymph nodes, no tumor seen (0/6).

D: Lymph nodes, right pelvic, lymph node dissection

- Six lymph nodes, no tumor seen (0/6).

E: Uterus, cervix, bilateral fallopian tubes and ovaries, robotic hysterectomy and bilateral salpingo-oophorectomy

Location of tumor: endometrium

Histologic type: endometrioid adenocarcinoma with lymphocytic response

Histologic grade: overall FIGO grade 3 (architectural grade 3, nuclear grade 3) (E7)

Extent of invasion:

Myometrial invasion: superficial myometrial invasion is present

Depth: 1 mm Wall thickness: 2.1 cm Percent: 5% (E7)

Serosal involvement: absent

Lower uterine segment involvement: absent

Cervical involvement: absent

Adnexal involvement: absent

Other sites: not applicable

[page 2 of 5]
Cervical vaginal margin and distance: widely free of tumor

Lymphovascular space invasion: absent

Regional lymph nodes:

Total number involved: 0

Total number examined: 24

Other pathologic findings:

- Myometrium with leiomyomas with hyalinization
- Cervix with Nabothian cysts.

Hormone receptor status: ER and PR, by immunohistochemistry, pending; final results will be issued in an addendum report (E7).

AJCC pathologic staging: pT1b pN0 pMx; FIGO stage grouping: IB

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Right ovary:

- Atrophic ovary, no tumor seen.

Left ovary:

- Atrophic ovary, no tumor seen.

Right fallopian tube:

- Paratubal cyst, no tumor seen.

Left fallopian tube:

- No tumor seen.

Clinical History:

The patient with a clinical diagnosis of endometrial cancer.

Gross Description:

Received are five appropriately labeled containers.

Container A is additionally labeled "left peri-aortic nodes." The container holds an aggregate of fibrofatty tissue that measures 2.2 x 1.5 x 0.8 cm. Two candidate lymph nodes are identified with the smaller measuring 0.6 x 0.3 x 0.3 cm and the larger measuring 0.7 x 0.4 x 0.3 cm.

Block Summary:

A1 - two candidate lymph nodes, not bisected

A2 - remainder of fatty tissue associated with lymph nodes

[page 3 of 5]
Container B is additionally labeled "right peri-aortic nodes." The container holds an aggregate of fibrofatty tissue that measures 4.2 x 3.0 x 1.5 cm. Six candidate lymph nodes are identified, with the largest measuring 2.0 x 1.5 x 0.3 cm and the smallest measuring 0.6 x 0.3 x 0.3 cm.

Block summary:

B1-B2 - largest candidate lymph node, bisected (one half per cassette)

B3 - two candidate lymph nodes, not bisected

B4-B6 - three candidate lymph nodes, bisected (one lymph node per cassette)

B7-B11 - remainder of fatty tissue associated with specimen

Container C is additionally labeled "left pelvic nodes." The container holds one fibrofatty aggregate of tissue that measures 5.0 x 3.6 x 2.0 cm. Five candidate lymph nodes are identified with the largest measuring 3.0 x 1.5 x 1.0 cm and the smallest measuring 1.0 x 0.6 x 0.4 cm.

Block summary:

C1,C2 - largest candidate lymph node, bisected

C3-C4 - one candidate lymph node, bisected (one half per cassette)

C5-C6 - two candidate lymph nodes, bisected (one lymph node per cassette)

C7 - one candidate lymph node, not bisected

C8-C13 - remainder of fatty tissue associated with specimen

Container D is additionally labeled "right pelvic nodes." The container holds one aggregate of fibrofatty tissue that measures 4.9 x 3.6 x 2.0 cm. Five candidate lymph nodes are identified with the largest measuring 3.0 x 1.2 x 1.0 cm. The smallest measures 0.5 x 0.3 x 0.3 cm.

Block summary:

D1-D4 - largest candidate lymph node, quadrisected (one quarter per cassette)

D5 - two candidate lymph nodes, not bisected

D6 - one candidate lymph node, not bisected (fragmented)

D7 - one candidate lymph node, bisected

D8-D13 - remainder of fatty tissue associated with specimen

Container E:

Adnexa: present bilaterally

Weight: 160.9 grams

Shape: pear shaped

Dimensions:

height: 11.5 cm

[page 4 of 5]
anterior to posterior width: 5.0 cm

breadth at fundus: 8.0 cm

Serosa: smooth; anterior=blue, posterior=black

Cervix:

length of endocervical canal: 3.0 cm

ectocervix: tan in color

endocervix: tan in color

Endomyometrium:

length of endometrial cavity: 3.2 cm

width of endometrial cavity at fundus: 3.0 cm

tumor findings:

dimensions: 3.5 x 2.5 x 1.5 cm

appearance: tan to dark brown in color with a fungating growth pattern

location and extent: superior aspect of the uterine fundus with some extension into the mid corpus area

myometrial invasion: no apparent invasion

thickness of myometrial wall at deepest gross invasion: 1.0 cm

other findings or comments: There is a large intrauterine leiomyoma at the superior aspect of the uterine fundus that measures 3.0 x 3.0 x 2.0 cm. No areas of necrosis or hemorrhage are identified.

Adnexa:

Right ovary:

dimensions: 1.8 x 1.8 x 0.5 cm

external surface: tan/yellow and smooth

cut surface: shows tan/yellow parenchyma with no masses or hemorrhage

Right fallopian tube:

dimensions: 4.6 cm in length and 0.6 cm in diameter

other findings: fimbria are identified

Left ovary:

dimensions: 1.6 x 1.1 x 0.6 cm

external surface: tan/yellow and smooth

cut surface: shows tan/yellow parenchyma with no masses or hemorrhage

Left fallopian tube:

dimensions: 4.0 cm in length and 0.6 cm in diameter

other findings: fimbriae are identified

Lymph nodes: Please see Specimens A-D.

Other comments: none

Digital photograph taken: no

Tissue submitted for special investigations: yes; Tissue submitted for Tissue procurement

Block Summary:

E1 - anterior cervix

E2 - anterior lower uterine segment

[page 5 of 5]
E3-E4 - anterior mid corpus
E5-E7 - anterior upper corpus/fundus (area of deepest invasion)
E8 - posterior cervix
E9 - two representative sections of intrauterine leiomyoma
E10 - posterior lower uterine segment
E11 - posterior mid corpus
E12 - posterior upper corpus/fundus
E13 - right ovary and fallopian tube
E14 - left ovary and fallopian tube
E15 - representative sections of intrauterine leiomyomas

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed by Dr.

Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the manufacturer. These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Signature

Resident Physician:

Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Procedures/Addenda:

Addendum

Addendum

ER and PR are performed on a representative block of endometrial tumor (E7). The tumor is strongly and diffusely positive for ER (3+, 95%) and PR (3+, 95%), with appropriately staining positive and negative controls.

Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the manufacturer. These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file 9b87cd92-8b64-439a-a9ff-9d2eb03e86a1 (TCGA-EY-A1GC.62D18250-0D82-43AB-AADE-E152D6FF74BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).